Gene-level copy-number profile of tumor specimen TCGA-43-2576-01A from TCGA case TCGA-43-2576, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.4 years (22,805 days).
Specimen TCGA-43-2576-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.dfcb25ee-9b53-4f7e-aae9-80de76084bb3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-2576-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2881006e-a79d-44d3-9e53-e1510233d333

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 90; copy number 1: 290; copy number 2: 13,625; copy number 3: 12,192; copy number 4: 23,280; copy number 5: 7,265; copy number 6: 1,546; copy number 7: 552; copy number 8: 381; copy number 9: 194; copy number 10: 4; copy number 11: 28; copy number 12: 222; copy number 13: 29; copy number 16: 102; copy number 17: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-2576-01A-01D-0844-01): tumor purity 0.27, ploidy 3.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–1,057,552, 26 genes: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–23,672,387, 18 genes (within-gene range 0–2): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2.
- chr13:66,218,250–69,408,735, 29 genes: MIR4704, TRIM60P19, PCDH9, PCDH9-AS1, RNU7-87P, PCDH9-AS2, PCDH9-AS3, PCDH9-AS4, AL160254.1, RPSAP53, LINC00364, AL512452.1, BCRP9, NPM1P22, OR7E111P, OR7E33P, AL590027.1, ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383, SRSF1P1.
- chr13:69,802,940–69,803,041, 1 gene: RNY3P10.
- chr13:82,778,208–83,145,903, 3 genes: AL445255.1, GYG1P2, AL512782.1.
- chr13:84,086,802–85,837,532, 12 genes (within-gene range 0–4): AL162493.1, MTND4P1, MTND5P3, LINC00333, AL445588.1, AL356313.1, LINC00375, AL160154.1, LINC00351, AL356413.1, SLITRK6, AL162373.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 593 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–148,288,951, 167 genes, copy number 9 (broad region; genes not listed).
- chr1:148,295,180–148,344,638, 6 genes, copy number 9: LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21.
- chr8:38,030,534–48,824,062, 203 genes, copy number 12 (broad region; genes not listed).
- chr13:90,781,766–92,873,682, 21 genes, copy number 9 (within-gene range 4–9): RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1, GPC5, AL356118.1, AL162456.1, RNU4ATAC3P, FABP5P4, AL157815.1, GPC5-AS2, AL159152.1.
- chr13:94,436,811–96,053,482, 28 genes, copy number 13: DCT, TGDS, GPR180, RNA5SP36, LINC00391, RN7SL585P, SOX21-AS1, SOX21, BRD7P5, RPL21P112, LINC00557, AL139381.1, RNU6-62P, ABCC4, RNY3P8, RNY4P27, MEMO1P5, CLDN10, CLDN10-AS1, DZIP1, DNAJC3-DT, DNAJC3, MTND5P2, MTND6P18, MTCYBP3, AL138955.1, UGGT2, HMGN1P24.
- chr13:96,169,545–96,169,847, 1 gene, copy number 13: RN7SL164P.
- chr13:101,452,593–101,720,856, 1 gene, copy number 10 (within-gene range 5–10): ITGBL1.
- chr13:101,717,564–101,802,488, 3 genes, copy number 10: AL160153.1, RNU1-24P, HMGB3P7.
- chr13:104,125,930–114,337,626, 163 genes, copy number 11–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 290. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
